Somatic mutation profile of tumor specimen 0DIFJ1 from CCDI case PBBVRB, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Neoplasm, uncertain whether benign or malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 8.5 years (3,095 days).
Specimen 0DIFJ1: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e85d4d78-afb8-4080-a8de-36a7d2d1490f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DIFIJ (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/dcfa260b-a2a8-45da-b603-51e1c198e129

The open-access MAF lists 2 somatic variants for this specimen: 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RAVER1 | c.1174-63A>G | Intron (SNP) | VAF 3/16 reads (19%) | called by muse, varscan2
- TSR1 | c.*769C>T | 3'UTR (SNP) | VAF 4/25 reads (16%) | called by muse, varscan2
